Somatic mutation profile of tumor specimen HCM-CSHL-0582-C18-06A (aliquot HCM-CSHL-0582-C18-06A-11D-A82H-36) from HCMI case HCM-CSHL-0582-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 56.2 years (20,518 days).
Specimen HCM-CSHL-0582-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f08af4e4-e2ba-4e31-9a00-b09ad4ad9cc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0582-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0582-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3a3021d-5073-4aad-8729-ebf06c826d1b

The open-access MAF lists 192 somatic variants for this specimen: 123 protein-altering or splice-affecting, 60 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 60, Nonsense Mutation 9, Intron 7, Splice Region 3, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 332/361 reads (92%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 167/291 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 320/382 reads (84%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, varscan2
- ADAM33 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 169/584 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100597856; called by muse, mutect2, varscan2
- ADAMTSL3 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54459324; called by muse, mutect2
- ADGRG4 | c.7871C>T p.T2624M | Missense Mutation (SNP) | VAF 227/243 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54966971; called by muse, mutect2, varscan2
- ALB | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 145/167 reads (87%) | catalogued as COSV55739341; called by muse, mutect2, varscan2
- ANKFN1 | c.3256G>A p.A1086T (on ENST00000653862; = p.A939T on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 286/317 reads (90%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.626); catalogued as rs1477683766, COSV73719858; called by muse, varscan2
- AP1M2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 151/288 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754237081, COSV51569463; called by muse, mutect2, varscan2
- AP3B2 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs765669791; called by muse, mutect2, varscan2
- APBA2 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 170/370 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs764880305, COSV68789491; called by muse, mutect2, varscan2
- ARHGAP30 | c.28_30del p.K10del | In Frame Del (DEL) | VAF 230/518 reads (44%) | catalogued as rs775704930; called by pindel, varscan2
- BAHCC1 | c.7468C>T p.P2490S | Missense Mutation (SNP) | VAF 202/227 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1158128210; called by muse, mutect2, varscan2
- CCL26 | c.186G>T p.V62= | Splice Region (SNP) | VAF 169/253 reads (67%) | catalogued as COSV50013709; called by muse, mutect2, varscan2
- CDH2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775708988, COSV52279355, COSV52293176; called by muse, varscan2
- CFAP47 | c.8137G>A p.A2713T | Missense Mutation (SNP) | VAF 109/127 reads (86%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV66216178; called by muse, mutect2, varscan2
- CLVS2 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 42/522 reads (8%) | catalogued as COSV51559397; called by muse, mutect2
- COL4A4 | c.1543G>C p.G515R | Missense Mutation (SNP) | VAF 177/321 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306625; called by muse, mutect2, varscan2
- CSMD1 | c.5407T>A p.C1803S (on ENST00000520002; = p.C1802S on NM_033225.6) | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100151227; called by muse, mutect2, varscan2
- DCAF12L2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 491/521 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100758422; called by muse, mutect2, varscan2
- DLG5 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); catalogued as rs779423863, COSV64946586; called by muse, mutect2
- DMD | c.4088A>G p.K1363R | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.283); catalogued as COSV63732568, COSV63756777; called by muse, mutect2, varscan2
- DOT1L | c.4132G>A p.G1378R | Missense Mutation (SNP) | VAF 192/556 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs1415903069; called by muse, mutect2, varscan2
- DYNC1I1 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 125/457 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs374032937; called by muse, mutect2, varscan2
- EDC4 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 133/310 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.332); catalogued as rs774004293; called by muse, mutect2, varscan2
- EFNB2 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 309/1065 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.153); catalogued as rs1187894749, COSV55366831; called by muse, mutect2, varscan2
- EFS | c.1251G>A p.Q417= | Splice Region (SNP) | VAF 110/273 reads (40%) | catalogued as COSV53731168; called by muse, mutect2, varscan2
- EZHIP | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 200/369 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs782321744, COSV57956911, COSV57957472; called by muse, mutect2, varscan2
- GALNT13 | c.41C>G p.S14W | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67217436, COSV67238875; called by muse, mutect2, varscan2
- H2BC3 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 100/173 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs1281968074; called by muse, mutect2, varscan2
- HEPHL1 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 230/368 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs763629616; called by muse, varscan2
- HSH2D | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 362/533 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs369080669; called by muse, mutect2, varscan2
- IGLV2-23 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs527861280; called by muse, mutect2, varscan2
- IRX1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 275/360 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57361291; called by muse, mutect2, varscan2
- KDM5A | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 200/339 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238638; called by muse, mutect2, varscan2
- KHSRP | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 212/330 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101231158, COSV101231213; called by muse, mutect2, varscan2
- MCAT | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs148085512; called by muse, mutect2, varscan2
- NAPA | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs774144496; called by muse, mutect2, varscan2
- NKAIN2 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100864094; called by muse, mutect2, varscan2
- NKG7 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 124/302 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765079634, COSV52467451; called by muse, mutect2, varscan2
- NPIPA1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 148/916 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs778271375; called by muse, mutect2, varscan2
- NYAP2 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs200139665; called by muse, mutect2, varscan2
- OR6Y1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56931681, COSV56931737; called by muse, mutect2, varscan2
- PHLPP1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 165/201 reads (82%) | SIFT deleterious, low confidence (0.03); catalogued as rs936158178; called by muse, mutect2, varscan2
- PLEKHF2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 76/227 reads (33%) | catalogued as COSV59541957; called by muse, mutect2, varscan2
- PPP1R9A | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs745926624, COSV56897461; called by muse, mutect2, varscan2
- PRAMEF12 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 226/256 reads (88%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs763764259; called by muse, mutect2, varscan2
- PTPRS | c.4634G>A p.R1545H | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754177433; called by muse, varscan2
- RNF40 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1441685970; called by muse, mutect2, varscan2
- RTL1 | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 143/355 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs756553297, COSV66017006; called by muse, mutect2, varscan2
- SCART1 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 163/531 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1043834419; called by muse, mutect2, varscan2
- SMAD4 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688309; called by muse, mutect2, varscan2
- THRB | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 119/275 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs758209560, COSV62838162; called by muse, mutect2, varscan2
- THSD7B | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 107/347 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs781503094, COSV55706486; called by muse, mutect2, varscan2
- TM6SF2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 269/397 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766513047, COSV66985025; called by muse, mutect2, varscan2
- TP73 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 151/175 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756287596; called by muse, mutect2, varscan2
- UBE4A | c.1466C>G p.T489S (on ENST00000252108 / NM_001204077.2; = p.T496S on NM_004788.4) | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs782189041; called by muse, mutect2, varscan2
- ZBTB7A | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs751149158, COSV100475993; called by muse, mutect2, varscan2
- ZDHHC8 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 157/329 reads (48%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.644); catalogued as rs184990183; called by muse, mutect2, varscan2
- ZNF135 | c.1744G>A p.E582K (on ENST00000313434 / NM_001289401.2; = p.E594K on NM_003436.4) | Missense Mutation (SNP) | VAF 151/292 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as COSV57881387; called by muse, mutect2, varscan2
- ZNF41 | c.2203A>T p.S735C | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV99058131; called by muse, mutect2, varscan2
- ZNF615 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs201004441, COSV100943713, COSV65034791; called by muse, mutect2, varscan2
- ZNF804A | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100170140; called by muse, mutect2, varscan2
- AARD | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 195/703 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS8 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 52/940 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.145); called by muse, mutect2
- ADAMTSL3 | c.25T>A p.W9R | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- ADGRB1 | c.1784C>G p.P595R | Missense Mutation (SNP) | VAF 113/383 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARID2 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 115/567 reads (20%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- AWAT1 | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.305); called by muse, mutect2
- BCOR | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CACNA1B | c.1538C>A p.T513N | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- CAMK2A | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 93/172 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CDH20 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 110/154 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB1 | c.3859C>T p.P1287S | Missense Mutation (SNP) | VAF 121/224 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CSMD1 | c.6193T>A p.F2065I (on ENST00000520002; = p.F2064I on NM_033225.6) | Missense Mutation (SNP) | VAF 113/153 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCHS1 | c.4751T>G p.L1584R | Missense Mutation (SNP) | VAF 231/376 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- DCHS1 | c.4750C>G p.L1584V | Missense Mutation (SNP) | VAF 230/375 reads (61%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- DISP3 | c.3673A>C p.I1225L | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DMTN | c.609_616dup p.R206Kfs*28 | Frame Shift Ins (INS) | VAF 28/40 reads (70%) | called by mutect2, varscan2
- DNAH7 | c.6556G>T p.V2186F | Missense Mutation (SNP) | VAF 155/274 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DOCK2 | c.3542T>A p.L1181H | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EFCAB8 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- EPRS1 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- IGKV1-33 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- INSIG1 | c.366C>G p.I122M | Missense Mutation (SNP) | VAF 84/558 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- KRT86 | c.784A>C p.K262Q | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MAP1A | c.7516T>A p.S2506T | Missense Mutation (SNP) | VAF 52/612 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- MAP3K15 | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MASTL | c.2486T>A p.L829Q (on ENST00000375940 / NM_001372029.1; = p.L828Q on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSL2 | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 113/219 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- MUC22 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 140/766 reads (18%) | SIFT tolerated (0.33); called by muse, mutect2, varscan2
- NAV3 | c.4300C>T p.Q1434* | Nonsense Mutation (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2, varscan2
- NFASC | c.815G>A p.G272E (on ENST00000339876 / NM_001378329.1; = p.G283E on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NOL6 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPSR1 | c.681C>T p.S227= | Splice Region (SNP) | VAF 42/462 reads (9%) | called by muse, mutect2
- NPY2R | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 264/317 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NT5C1B | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 148/254 reads (58%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR2T35 | c.548C>G p.A183G | Missense Mutation (SNP) | VAF 73/537 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDH11Y | c.3747C>G p.S1249R | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- PCDHGA3 | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 13/444 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZD2 | c.8027G>A p.G2676D | Missense Mutation (SNP) | VAF 146/474 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRICKLE1 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- PRX | c.1973A>G p.Q658R | Missense Mutation (SNP) | VAF 148/365 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PTPRK | c.4102G>A p.G1368R (on ENST00000368215 / NM_001291984.2; = p.G1369R on NM_002844.4) | Missense Mutation (SNP) | VAF 226/494 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PUS1 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- REX1BD | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 32/1039 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.299); called by muse, mutect2
- RGPD8 | c.3191T>C p.V1064A | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.689); called by muse, varscan2
- RHPN1 | c.1606del p.A536Lfs*14 | Frame Shift Del (DEL) | VAF 54/485 reads (11%) | called by mutect2, pindel*
- RNF180 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2
- SAMD9 | c.3562C>T p.R1188W | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SIAH3 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 65/872 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2
- SLC4A4 | c.950T>G p.V317G (on ENST00000264485 / NM_001098484.3; = p.V273G on NM_003759.4) | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SPIDR | c.1774-1G>A p.X592_splice | Splice Site (SNP) | VAF 74/226 reads (33%) | called by muse, varscan2
- STAT3 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM185A | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 165/376 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNS1 | c.2446T>G p.S816A | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- TPTE | c.1052C>A p.A351D (on ENST00000618007 / NM_199261.4; = p.A333D on NM_199259.4) | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- USP17L22 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 114/1684 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.19); called by muse, mutect2
- VPS41 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 137/326 reads (42%) | called by muse, mutect2, varscan2
- WDR41 | c.615A>T p.E205D | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF613 | c.1808T>C p.V603A (on ENST00000293471 / NM_001031721.4; = p.V567A on NM_024840.4) | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF729 | c.367A>T p.R123* | Nonsense Mutation (SNP) | VAF 66/256 reads (26%) | called by muse, mutect2, varscan2
- APOA4 | c.612C>T p.Y204= | Silent (SNP) | VAF 80/535 reads (15%) | catalogued as rs201385362, COSV63361128; called by muse, mutect2, varscan2
- ASB11 | c.897C>T p.L299= | Silent (SNP) | VAF 175/182 reads (96%) | catalogued as rs751433388, COSV100729188; called by muse, mutect2, varscan2
- BFSP1 | c.783C>T p.D261= | Silent (SNP) | VAF 194/355 reads (55%) | catalogued as rs370330055; called by muse, mutect2, varscan2
- CAD | c.6198G>A p.E2066= | Silent (SNP) | VAF 42/406 reads (10%) | called by muse, mutect2
- CCDC168 | c.3615C>T p.V1205= | Silent (SNP) | VAF 227/757 reads (30%) | called by muse, mutect2, varscan2
- CCDC74B | c.1098G>A p.R366= | Silent (SNP) | VAF 34/517 reads (7%) | catalogued as rs1558717798, COSV100134441; called by muse, mutect2
- CCNA1 | c.606C>T p.G202= | Silent (SNP) | VAF 80/573 reads (14%) | called by muse, mutect2, varscan2
- CDH4 | c.480C>T p.N160= | Silent (SNP) | VAF 165/956 reads (17%) | catalogued as rs149210026; called by muse, mutect2, varscan2
- CHAC1 | c.168C>T p.F56= | Silent (SNP) | VAF 186/729 reads (26%) | catalogued as COSV71435900; called by muse, mutect2, varscan2
- CIT | c.4497C>T p.D1499= | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as rs780669729; called by muse, mutect2, varscan2
- CLEC2A | c.429C>T p.N143= | Silent (SNP) | VAF 60/247 reads (24%) | catalogued as rs377339235; called by muse, mutect2, varscan2
- CNGA2 | c.1104G>T p.V368= | Silent (SNP) | VAF 52/362 reads (14%) | called by muse, mutect2, varscan2
- COL4A1 | c.1419C>T p.D473= | Silent (SNP) | VAF 123/806 reads (15%) | catalogued as rs140440365, COSV65422031, COSV65423996; called by muse, mutect2, varscan2
- CR2 | c.2247C>T p.D749= | Silent (SNP) | VAF 20/616 reads (3%) | called by muse, mutect2
- CRB1 | c.4197C>G p.P1399= | Silent (SNP) | VAF 159/394 reads (40%) | called by muse, mutect2, varscan2
- CRNN | c.36C>T p.I12= | Silent (SNP) | VAF 180/478 reads (38%) | catalogued as rs1394330908, COSV55121122; called by muse, mutect2, varscan2
- CSMD1 | c.5406C>A p.P1802= (on ENST00000520002; = p.P1801= on NM_033225.6) | Silent (SNP) | VAF 45/79 reads (57%) | catalogued as COSV100144578; called by muse, mutect2, varscan2
- CTTNBP2 | c.4827T>C p.V1609= | Silent (SNP) | VAF 81/395 reads (21%) | called by muse, mutect2, varscan2
- DENND4B | c.1704A>C p.G568= | Silent (SNP) | VAF 48/922 reads (5%) | called by muse, mutect2
- DISP3 | c.3672C>A p.T1224= | Silent (SNP) | VAF 38/280 reads (14%) | called by muse, mutect2, varscan2
- ESR1 | c.768A>C p.R256= | Silent (SNP) | VAF 170/369 reads (46%) | called by muse, mutect2, varscan2
- FBXL7 | c.1146C>T p.N382= | Silent (SNP) | VAF 168/476 reads (35%) | catalogued as rs746695934, COSV61640788; called by muse, mutect2, varscan2
- FOXP4 | c.2002A>C p.R668= (on ENST00000307972 / NM_001012426.1; = p.R655= on NM_138457.3) | Silent (SNP) | VAF 135/1564 reads (9%) | catalogued as rs1310228620; called by muse, mutect2
- GKAP1 | c.531C>G p.L177= | Silent (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- GRM2 | c.642C>T p.G214= | Silent (SNP) | VAF 139/295 reads (47%) | catalogued as rs530569899, COSV56588351; called by muse, mutect2, varscan2
- GRM7 | c.204C>T p.G68= | Silent (SNP) | VAF 173/507 reads (34%) | catalogued as COSV63130114; called by muse, mutect2
- HOXC12 | c.87C>T p.F29= | Silent (SNP) | VAF 156/363 reads (43%) | catalogued as rs762300310, COSV54535266; called by muse, mutect2, varscan2
- HSD3B2 | c.1084C>A p.R362= | Silent (SNP) | VAF 70/195 reads (36%) | catalogued as COSV65592533; called by muse, mutect2, varscan2
- IRS4 | c.15C>T p.S5= | Silent (SNP) | VAF 54/204 reads (26%) | catalogued as rs969865599; called by muse, mutect2, varscan2
- ISLR | c.198G>A p.P66= | Silent (SNP) | VAF 148/310 reads (48%) | catalogued as rs200581049; called by muse, mutect2, varscan2
- KMT2B | c.5769G>A p.P1923= | Silent (SNP) | VAF 228/478 reads (48%) | catalogued as rs375845181; called by muse, mutect2, varscan2
- LRP1 | c.3702C>T p.S1234= | Silent (SNP) | VAF 117/276 reads (42%) | called by muse, mutect2, varscan2
- MANEA | c.907C>T p.L303= | Silent (SNP) | VAF 73/265 reads (28%) | called by muse, mutect2, varscan2
- MDN1 | c.13515A>G p.S4505= | Silent (SNP) | VAF 74/355 reads (21%) | called by muse, mutect2, varscan2
- MEIS1 | c.699C>T p.S233= | Silent (SNP) | VAF 176/300 reads (59%) | catalogued as rs372577277; called by muse, mutect2, varscan2
- OR4D1 | c.288C>A p.G96= | Silent (SNP) | VAF 15/391 reads (4%) | catalogued as COSV52124772; called by muse, mutect2
- PCDHA11 | c.1029C>T p.N343= | Silent (SNP) | VAF 46/406 reads (11%) | catalogued as rs371110623; called by muse, mutect2, varscan2
- PDE4D | c.399G>T p.R133= | Silent (SNP) | VAF 148/283 reads (52%) | called by muse, mutect2, varscan2
- PPFIA4 | c.2742C>T p.T914= (on ENST00000447715; = p.T915= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/543 reads (16%) | called by muse, mutect2, varscan2
- PSTK | c.597T>G p.P199= | Silent (SNP) | VAF 70/407 reads (17%) | called by muse, mutect2, varscan2
- QDPR | c.555G>A p.L185= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as COSV99845975; called by muse, mutect2
- RALGDS | c.2361C>T p.S787= | Silent (SNP) | VAF 117/434 reads (27%) | catalogued as rs774208713; called by muse, mutect2, varscan2
- RHPN2 | c.1359G>A p.T453= | Silent (SNP) | VAF 154/356 reads (43%) | catalogued as rs780058656; called by muse, mutect2, varscan2
- RIMBP2 | c.1275C>T p.N425= | Silent (SNP) | VAF 137/323 reads (42%) | catalogued as rs150377943, COSV55471554; called by muse, mutect2, varscan2
- SENP6 | c.33G>A p.G11= | Silent (SNP) | VAF 54/399 reads (14%) | catalogued as COSV59192266; called by muse, mutect2, varscan2
- SERPINA7 | c.174T>C p.T58= | Silent (SNP) | VAF 360/372 reads (97%) | catalogued as CD002711, COSV59667119; called by muse, mutect2, varscan2
- SLC12A1 | c.2256G>A p.A752= | Silent (SNP) | VAF 120/243 reads (49%) | catalogued as rs149454210; called by muse, mutect2, varscan2
- SLCO6A1 | c.75G>A p.A25= | Silent (SNP) | VAF 234/435 reads (54%) | catalogued as rs1440160929, COSV65806599; called by muse, mutect2, varscan2
- SMARCA5 | c.1113A>T p.T371= | Silent (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- SPAM1 | c.246C>T p.N82= | Silent (SNP) | VAF 113/450 reads (25%) | catalogued as rs1431798930, COSV99773193; called by muse, mutect2, varscan2
- SYNC | c.33C>T p.D11= | Silent (SNP) | VAF 198/412 reads (48%) | catalogued as rs1244605029; called by muse, mutect2, varscan2
- TBXT | c.600C>T p.N200= | Silent (SNP) | VAF 63/138 reads (46%) | catalogued as rs374566002; called by muse, mutect2, varscan2
- TEX45 | c.18C>T p.L6= | Silent (SNP) | VAF 258/425 reads (61%) | called by muse, mutect2, varscan2
- TNR | c.2115C>T p.I705= | Silent (SNP) | VAF 99/572 reads (17%) | called by muse, mutect2, varscan2
- TRAF4 | c.12C>T p.F4= | Silent (SNP) | VAF 18/225 reads (8%) | catalogued as rs776356493; called by muse, mutect2
- TTC17 | c.69C>T p.L23= | Silent (SNP) | VAF 39/667 reads (6%) | catalogued as rs1449692353, COSV99234549; called by muse, mutect2
- TTN | c.85758G>A p.K28586= (on ENST00000591111; = p.K21162= on NM_003319.4) | Silent (SNP) | VAF 33/406 reads (8%) | called by muse, mutect2
- VMAC | c.366T>G p.A122= | Silent (SNP) | VAF 66/541 reads (12%) | called by muse, mutect2, varscan2
- ZER1 | c.6G>A p.A2= | Silent (SNP) | VAF 101/264 reads (38%) | catalogued as rs137907314; called by muse, mutect2, varscan2
- ZNF888 | c.1944C>T p.Y648= | Silent (SNP) | VAF 84/218 reads (39%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59924C>T | Intron (SNP) | VAF 23/242 reads (10%) | catalogued as COSV52243257; called by muse, mutect2, varscan2
- DLGAP1 | c.958-30984T>A | Intron (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- EYS | c.1766+2591C>A | Intron (SNP) | VAF 23/314 reads (7%) | called by muse, mutect2
- GABRG2 | c.1249-81A>T | Intron (SNP) | VAF 77/234 reads (33%) | called by muse, mutect2, varscan2
- LINC00960 | chr3:75679077 C>G | 3'Flank (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3730_1999+3731dup | Intron (INS) | VAF 95/286 reads (33%) | called by mutect2, pindel, varscan2
- PKD1L2 | n.1325G>T | RNA (SNP) | VAF 85/202 reads (42%) | catalogued as rs1369054754; called by muse, mutect2, varscan2
- PRKCE | c.1437+210G>A | Intron (SNP) | VAF 83/331 reads (25%) | catalogued as rs1243549728; called by muse, mutect2, varscan2
- PRSS40A | n.142-2203G>A | Intron (SNP) | VAF 47/1187 reads (4%) | catalogued as rs1195177954; called by muse, mutect2
